Somatic mutation profile of tumor specimen MMRF_1071_2_BM_CD138pos (aliquot MMRF_1071_2_BM_CD138pos_T1_KHS5U_L13756) from MMRF case MMRF_1071, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.2 years (15,431 days).
Specimen MMRF_1071_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc105e30-1349-4ae9-bf20-df2dfb4e3220.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1071_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1071_2_PB_WBC_C2_KHS5U_L13757; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb2c4689-8222-4369-9f3e-acdd8696b824

The open-access MAF lists 82 somatic variants for this specimen: 42 protein-altering or splice-affecting, 5 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 23, Silent 5, Intron 4, Frame Shift Ins 3, 5'Flank 3, 5'UTR 3, Splice Site 2, 3'Flank 1, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/110 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | hotspot (GDC flag); catalogued as rs1131690863, CM941204, COSV57294817; ClinVar: pathogenic; called by muse, mutect2
- AMPH | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272402161, COSV57740359; called by muse, mutect2, varscan2
- ANK1 | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1235955784; called by muse, mutect2
- BCHE | c.401dup p.N134Kfs*24 | Frame Shift Ins (INS) | VAF 61/173 reads (35%) | catalogued as rs764588882; called by mutect2, pindel, varscan2
- BCL7A | c.561+7C>T | Splice Region (SNP) | VAF 59/147 reads (40%) | catalogued as rs556323322; called by muse, mutect2, varscan2
- CAPN5 | c.1616G>A p.R539H (on ENST00000456580; = p.R499H on NM_004055.5) | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs140490506; called by muse, mutect2, varscan2
- CYP46A1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99029138; called by muse, mutect2, varscan2
- DNAH6 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs548615248, COSV52884395; called by muse, mutect2, varscan2
- FOCAD | c.4450G>A p.G1484S | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as COSV100620094; called by muse, mutect2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70D | c.172A>C p.I58L | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1555598137; called by muse, varscan2
- IGLL5 | c.206+2T>A p.X69_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as rs561122720, COSV73250168, COSV73251186; called by muse, varscan2
- KDM4B | c.2968G>A p.G990S | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs770960571; called by muse, mutect2, varscan2
- KHDRBS3 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs369245979, COSV63416496; called by muse, mutect2, varscan2
- LRCH2 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.062); catalogued as COSV57757861; called by muse, mutect2, varscan2
- PNRC1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.112); catalogued as rs1336772183; called by muse, mutect2, varscan2
- REXO1 | c.3373G>T p.V1125F | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99402708; called by muse, mutect2, varscan2
- SGMS2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 89/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763770355, COSV62988994; called by muse, mutect2, varscan2
- TMEM163 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs974651667, COSV56112888; called by muse, mutect2, varscan2
- TRIM21 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 118/206 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as rs780484565; called by muse, mutect2, varscan2
- TRIM55 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as COSV52542738; called by muse, mutect2, varscan2
- AHSG | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 115/359 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARMC2 | c.1681G>T p.G561W | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C12orf50 | c.642A>C p.E214D | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CDH11 | c.1577G>C p.R526T | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDKN2AIP | c.35A>G p.N12S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CLIC2 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 112/153 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM136A | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); called by muse, varscan2
- FRMPD3 | c.1032dup p.S345Lfs*47 | Frame Shift Ins (INS) | VAF 38/72 reads (53%) | called by mutect2, pindel, varscan2
- IFRD2 | c.737A>G p.H246R | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.498); called by muse, mutect2
- LRP12 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); called by muse, mutect2
- MKNK2 | c.51+2_51+6del p.X17_splice | Splice Site (DEL) | VAF 131/281 reads (47%) | called by mutect2, pindel, varscan2
- NF1 | c.3236T>G p.L1079R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3C2B | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- RBBP6 | c.3996T>A p.D1332E | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2
- RSL1D1 | c.1448_1449dup p.P484Nfs*36 | Frame Shift Ins (INS) | VAF 43/166 reads (26%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SRPK1 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SV2B | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TRPM6 | c.1693T>A p.S565T | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- UCK2 | c.20A>C p.Q7P | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.019); called by muse, mutect2
- EVC2 | c.2466G>A p.Q822= | Silent (SNP) | VAF 63/158 reads (40%) | called by muse, mutect2, varscan2
- FAT2 | c.2322A>G p.V774= | Silent (SNP) | VAF 127/258 reads (49%) | called by muse, mutect2, varscan2
- HOXA3 | c.1011G>A p.G337= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs956468687, COSV100415678; called by muse, mutect2
- NOSIP | c.843C>T p.T281= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as rs761009026; called by muse, mutect2, varscan2
- RNF31 | c.2355G>T p.L785= | Silent (SNP) | VAF 83/221 reads (38%) | catalogued as COSV60727116; called by muse, mutect2, varscan2
- ABHD13 | c.*2149G>T | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- AC004947.2 | chr7:26533934 C>A | 5'Flank (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- BIRC6 | c.*324_*326del | 3'UTR (DEL) | VAF 4/33 reads (12%) | called by pindel, varscan2
- C9orf40 | c.-1C>T | 5'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs1295961725; called by muse, mutect2, varscan2
- CCDC33 | c.*13G>A | 3'UTR (SNP) | VAF 151/457 reads (33%) | catalogued as rs911208672; called by muse, mutect2, varscan2
- CCL25 | c.-1C>G | 5'UTR (SNP) | VAF 61/113 reads (54%) | called by muse, mutect2, varscan2
- CEP78 | c.*7627G>C | 3'UTR (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- FAM117B | c.*3213G>A | 3'UTR (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- FBXO41 | c.*899C>G | 3'UTR (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- FGF13 | c.*1003T>A | 3'UTR (SNP) | VAF 38/57 reads (67%) | called by muse, mutect2, varscan2
- HSPD1 | c.970-55G>C | Intron (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- KBTBD11 | c.-485C>T | 5'UTR (SNP) | VAF 65/206 reads (32%) | catalogued as rs571556550; called by muse, mutect2, varscan2
- KCNA4 | c.*49T>G | 3'UTR (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- KCNMB3P1 | n.2067C>A | RNA (SNP) | VAF 77/242 reads (32%) | called by muse, mutect2, varscan2
- KPNA6 | c.*2159A>C | 3'UTR (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- KPNA6 | c.*2528A>G | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- LRRN3 | c.*272A>G | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851342 C>T | 5'Flank (SNP) | VAF 43/165 reads (26%) | catalogued as rs544762978; called by muse, mutect2, varscan2
- MYO6 | c.*1539G>A | 3'UTR (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- NDRG4 | c.*1974T>G | 3'UTR (SNP) | VAF 26/80 reads (33%) | catalogued as rs1231356133; called by muse, mutect2, varscan2
- NPC1L1 | c.*77G>A | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- NTM | c.*556A>T | 3'UTR (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- PFKP | c.1684-270G>A | Intron (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- PHF24 | c.*4105G>A | 3'UTR (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- PIK3CD | c.-138+2435C>G | Intron (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- PRKAR1B | chr7:549332 A>C | 3'Flank (SNP) | VAF 66/194 reads (34%) | called by muse, mutect2
- RIMS4 | c.*421C>T | 3'UTR (SNP) | VAF 9/185 reads (5%) | catalogued as rs1005818833; called by muse, mutect2
- RSPH10B2 | chr7:6751516 C>A | 5'Flank (SNP) | VAF 60/260 reads (23%) | called by muse, mutect2, varscan2
- RTKN2 | c.488+473T>A | Intron (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- TBR1 | c.*1369del | 3'UTR (DEL) | VAF 28/102 reads (27%) | called by mutect2, varscan2
- TMEM254 | c.*380A>G | 3'UTR (SNP) | VAF 181/581 reads (31%) | called by muse, mutect2, varscan2
- UBE2NL | c.*12C>A | 3'UTR (SNP) | VAF 110/148 reads (74%) | called by muse, mutect2, varscan2
- UGT3A1 | c.*1902A>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- UNC13A | c.*1155dup | 3'UTR (INS) | VAF 11/43 reads (26%) | catalogued as rs1287888888; called by mutect2, pindel, varscan2
- ZNF490 | c.*2525G>T | 3'UTR (SNP) | VAF 9/84 reads (11%) | catalogued as rs867344353; called by muse, mutect2
